Somatic mutation profile of tumor specimen 0E1HFB from CCDI case PBCWJX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E1HFB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8270b18-3189-47ff-af53-3356c82b10fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1HG5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcc1d4d2-7de0-40c6-99af-56034186e142

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDHGA8 | c.1572G>T p.Q524H | Missense Mutation (SNP) | VAF 38/767 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.182); catalogued as COSV53972805; called by muse, mutect2
- CWC22 | c.1664T>G p.L555* | Nonsense Mutation (SNP) | VAF 107/428 reads (25%) | called by muse, mutect2, varscan2
- HMX1 | c.344_345del p.R115Lfs*16 | Frame Shift Del (DEL) | VAF 40/215 reads (19%) | called by pindel, varscan2
- KDM5A | c.3072G>T p.E1024D | Missense Mutation (SNP) | VAF 44/542 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.264); called by muse, mutect2
- LILRB1 | c.196A>G p.T66A (on ENST00000427581; = p.T30A on NM_006669.6) | Missense Mutation (SNP) | VAF 46/341 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ZMIZ1 | c.1644G>T p.M548I | Missense Mutation (SNP) | VAF 19/506 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
